Somatic mutation profile of tumor specimen TCGA-A5-A1OK-01A (aliquot TCGA-A5-A1OK-01A-11D-A14K-09) from TCGA case TCGA-A5-A1OK, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 63.5 years (23,179 days).
Specimen TCGA-A5-A1OK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 42f61f26-fbd1-4ecf-b446-980cdd7cdb8e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A5-A1OK-10A (Blood Derived Normal), aliquot TCGA-A5-A1OK-10A-01D-A14K-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e211fd2d-a6b9-4d64-a821-f73342f1d6c2

The open-access MAF lists 74 somatic variants for this specimen: 60 protein-altering or splice-affecting, 12 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 12, Frame Shift Del 4, Nonstop Mutation 1, Nonsense Mutation 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 25/42 reads (60%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121434592, COSV62571334, COSV62576849; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MTOR | c.7499T>A p.I2500N | Missense Mutation (SNP) | VAF 14/76 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.353); catalogued as COSV63869065; called by muse, mutect2, varscan2
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 26/93 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SOX17 | c.1208G>T p.S403I | Missense Mutation (SNP) | VAF 12/32 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52024163; called by muse, mutect2, varscan2
- ACTRT2 | c.1051C>A p.L351M | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV101007648, COSV65759783; called by muse, mutect2, varscan2
- ACVR1B | c.1204G>T p.D402Y | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99231829; called by muse, mutect2, varscan2
- ADCY7 | c.1250C>T p.T417M | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs888316150, COSV99576070; called by muse, mutect2, varscan2
- ADGRL4 | c.1792C>T p.R598C | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs764619199, COSV66059595; called by muse, mutect2, varscan2
- ARHGAP20 | c.3100C>T p.P1034S | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV99505001; called by muse, mutect2, varscan2
- C17orf80 | c.1310G>A p.R437H | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs141607167; called by muse, mutect2
- CACNG5 | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.363); catalogued as rs772824396, COSV50059067; called by muse, mutect2, varscan2
- CCNA1 | c.122A>T p.E41V | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV99714792; called by muse, mutect2, varscan2
- CCT5 | c.1310C>T p.A437V | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.325); catalogued as rs149067488; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CGB7 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as rs1417276166, COSV100655105; called by muse, mutect2, varscan2
- CHD4 | c.3274C>T p.R1092W (on ENST00000357008 / NM_001363606.2; = p.R1105W on NM_001273.5) | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58898720; called by muse, mutect2, varscan2
- CMYA5 | c.6775G>A p.G2259S | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.01); catalogued as rs747610380, COSV71406253; called by muse, mutect2, varscan2
- DBF4 | c.427G>C p.V143L | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.123); catalogued as COSV99719536; called by muse, mutect2, varscan2
- DDO | c.854G>A p.R285Q (on ENST00000368924 / NM_001368172.1; = p.R226Q on NM_004032.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as rs750781798, COSV64469651; called by muse, mutect2, varscan2
- DSCC1 | c.965T>C p.I322T | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV100558394; called by muse, mutect2
- FZD7 | c.122T>A p.I41N | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.147); catalogued as COSV99637416; called by muse, mutect2, varscan2
- GAL3ST2 | c.185C>T p.T62M | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780795881, COSV99511115; called by muse, mutect2, varscan2
- GLRX | c.178T>C p.Y60H | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99428217; called by muse, mutect2, varscan2
- IL4R | c.1567C>A p.L523M | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.841); catalogued as COSV99405310; called by muse, mutect2
- ITGA1 | c.907C>T p.Q303* | Nonsense Mutation (SNP) | VAF 14/53 reads (26%) | catalogued as COSV99031422; called by muse, mutect2, varscan2
- KHSRP | c.1032G>A p.M344I | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV101231233; called by muse, mutect2, varscan2
- KIZ | c.1527C>G p.S509R | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as COSV99852304; called by muse, mutect2, varscan2
- KRT28 | c.1183G>T p.D395Y | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100137673; called by muse, mutect2, varscan2
- LCT | c.4496C>T p.T1499M | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as rs377167128, COSV99930216; called by muse, mutect2, varscan2
- MKI67 | c.4991C>G p.T1664R | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as COSV64072774; called by muse, varscan2
- MOG | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.191); catalogued as COSV100973095; called by muse, mutect2, varscan2
- NANOG | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs767551668, COSV57551872; called by muse, mutect2, varscan2
- NAV2 | c.844C>T p.P282S (on ENST00000396087 / NM_001244963.2; = p.P259S on NM_145117.5) | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.309); catalogued as COSV100586820; called by muse, mutect2
- NCK1 | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.456); catalogued as COSV99999793; called by muse, mutect2, varscan2
- OR9Q2 | c.566G>A p.C189Y | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100285504; called by muse, mutect2, varscan2
- PDE1B | c.208G>A p.V70I | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.332); catalogued as rs200096201; called by muse, mutect2
- PHGDH | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.548); catalogued as rs142988234; called by muse, mutect2, varscan2
- PHRF1 | c.3121C>T p.R1041C (on ENST00000264555 / NM_001286581.2; = p.R1040C on NM_020901.4) | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs372878846; called by muse, varscan2
- PIP4P1 | c.713G>T p.R238L | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV99164507; called by muse, mutect2, varscan2
- POLE | c.4886C>A p.A1629D | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100267858; called by muse, mutect2
- PRAG1 | c.2909G>A p.C970Y | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV100422658; called by muse, mutect2, varscan2
- PTGFRN | c.2036T>C p.I679T | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV101277440; called by muse, mutect2
- RADIL | c.2868G>T p.E956D | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.136); catalogued as COSV101271591; called by muse, mutect2
- RALGPS2 | c.1076G>T p.S359I | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV100244260; called by muse, mutect2
- SP110 | c.43C>A p.H15N | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.783); catalogued as COSV99283705; called by muse, mutect2
- ST6GAL2 | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 11/22 reads (50%) | PolyPhen benign (0); catalogued as rs562042019, COSV64526729; called by muse, mutect2, varscan2
- TCTN1 | c.1141G>T p.G381C (on ENST00000551590 / NM_001173975.3; = p.G367C on NM_024549.6) | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100886223; called by muse, mutect2
- TEX11 | c.1076C>T p.T359M (on ENST00000344304; = p.T344M on NM_031276.3) | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as rs760003842, COSV100721216; called by muse, mutect2, varscan2
- TLR7 | c.283G>A p.D95N | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0.427); catalogued as rs200138463, COSV101028077; called by muse, mutect2, varscan2
- TLR8 | c.2261C>A p.S754Y (on ENST00000218032 / NM_138636.5; = p.S772Y on NM_016610.4) | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99487225; called by muse, mutect2, varscan2
- TRAK2 | c.2717C>T p.P906L | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.454); catalogued as COSV100217075; called by muse, mutect2, varscan2
- TRIP10 | c.932G>A p.R311Q | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.557); catalogued as rs148404026, COSV57569693; called by muse, mutect2
- TXLNB | c.1932G>A p.M644I | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as COSV64444424; called by muse, mutect2, varscan2
- ZNF449 | c.577C>T p.L193F | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as COSV100203044; called by muse, mutect2, varscan2
- ZNF835 | c.298C>T p.R100W | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); catalogued as COSV101606267; called by muse, mutect2, varscan2
- ARID1A | c.2096del p.P699Lfs*43 | Frame Shift Del (DEL) | VAF 17/60 reads (28%) | called by mutect2, pindel, varscan2
- DQX1 | c.2154A>C p.*718Cext*15 | Nonstop Mutation (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2, varscan2
- HNF1B | c.1163_1181del p.S388Ifs*9 | Frame Shift Del (DEL) | VAF 11/62 reads (18%) | called by mutect2, pindel
- IGLV5-45 | c.193C>T p.P65S | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); called by muse, mutect2
- STK35 | c.1491del p.M498Cfs*9 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | called by mutect2, pindel
- ZFHX3 | c.7668_7669del p.Q2557Efs*21 | Frame Shift Del (DEL) | VAF 5/46 reads (11%) | called by pindel, varscan2
- CACNA2D4 | c.2493G>A p.V831= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as COSV54563682, COSV99766338; called by muse, mutect2, varscan2
- CFAP65 | c.1509C>A p.I503= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV99838412; called by muse, mutect2, varscan2
- DOCK1 | c.1926C>T p.V642= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as rs558498197, COSV54744213; called by muse, mutect2, varscan2
- DTX1 | c.1176C>T p.P392= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as rs1437835898, COSV99986469; called by muse, mutect2, varscan2
- FAM71F2 | c.768C>T p.C256= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as COSV101100725; called by muse, mutect2
- KIRREL2 | c.351G>A p.L117= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as COSV99384306; called by muse, mutect2
- MYH4 | c.1236G>A p.E412= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as COSV55118640; called by muse, mutect2, varscan2
- OR4M1 | c.324G>T p.G108= | Silent (SNP) | VAF 28/158 reads (18%) | catalogued as rs1199441762, COSV100271447, COSV60059635; called by muse, mutect2, varscan2
- P2RY8 | c.705G>A p.A235= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV101184155; called by muse, mutect2, varscan2
- SH2D5 | c.648G>A p.S216= (on ENST00000444387 / NM_001103161.2; = p.S132= on NM_001103160.2) | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as rs1461217520, COSV66707631; called by muse, mutect2, varscan2
- SMC1A | c.321C>A p.I107= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as COSV100447637; called by muse, mutect2, varscan2
- STXBP5 | c.2496C>T p.P832= (on ENST00000321680 / NM_001127715.2; = p.P796= on NM_139244.4) | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as rs1265324275, COSV99470790; called by muse, mutect2, varscan2
- PKD1L2 | chr16:81139583 C>T | 5'Flank (SNP) | VAF 7/55 reads (13%) | called by muse, mutect2, varscan2
- SERPINA13P | n.173A>G | RNA (SNP) | VAF 3/31 reads (10%) | catalogued as rs1260323897; called by muse, mutect2
